Somatic mutation profile of tumor specimen C3N-02252-74 (aliquot CPT0128890006) from CPTAC case C3N-02252, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; Tumor grade: G3.
Specimen C3N-02252-74: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaab668f-9b87-4475-abfa-a3eed262221e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02252-31 (Blood Derived Normal), aliquot CPT0130770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17348063-2166-4ff0-b71c-35f49dad3876

The open-access MAF lists 223 somatic variants for this specimen: 164 protein-altering or splice-affecting, 35 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 35, Nonsense Mutation 14, Frame Shift Del 10, Intron 10, 5'UTR 6, Splice Site 4, Splice Region 3, 5'Flank 2, 3'UTR 2, RNA 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1328C>A p.S443* | Nonsense Mutation (SNP) | VAF 41/142 reads (29%) | catalogued as rs1060503079, CM034900, COSV57294225, COSV57294594, COSV57318875; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 145/499 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.1507G>T p.V503L | Missense Mutation (SNP) | VAF 45/417 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61262006; called by muse, mutect2, varscan2
- ADAMTS13 | c.1356G>T p.R452S | Missense Mutation (SNP) | VAF 245/537 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV63023257; called by mutect2, varscan2
- ADCY8 | c.3170G>A p.W1057* | Nonsense Mutation (SNP) | VAF 30/121 reads (25%) | catalogued as rs1429431635, COSV53913362; called by muse, mutect2, varscan2
- AKAP14 | c.400G>C p.G134R | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.55); catalogued as COSV57629802; called by muse, mutect2
- ARID2 | c.1217A>G p.H406R | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.715); catalogued as COSV57606234; called by muse, mutect2, varscan2
- ARSF | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100839495; called by muse, mutect2, varscan2
- BICD1 | c.1438A>T p.M480L | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as COSV55684115; called by muse, mutect2, varscan2
- C1QTNF8 | c.491A>G p.Y164C | Missense Mutation (SNP) | VAF 87/446 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746468611, COSV60519593; called by muse, mutect2, varscan2
- CAPN6 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs868795243, COSV60695470; called by muse, mutect2, varscan2
- CDH12 | c.390G>T p.Q130H | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66416952; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1271C>A p.S424Y | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV65677341; called by muse, mutect2, varscan2
- CSMD3 | c.7471G>T p.E2491* (on ENST00000297405 / NM_001363185.1; = p.E2387* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 40/195 reads (21%) | catalogued as COSV52164484; called by muse, mutect2, varscan2
- DECR2 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs1282801082; called by muse, mutect2, varscan2
- DPPA5 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs747598051; called by muse, mutect2, varscan2
- ETV1 | c.353del p.L118Rfs*15 | Frame Shift Del (DEL) | VAF 84/264 reads (32%) | catalogued as COSV54147172; called by mutect2, pindel, varscan2
- EXD1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 66/307 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs374548709; called by muse, mutect2, varscan2
- GPR174 | c.876C>A p.Y292* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV52133652; called by muse, mutect2, varscan2
- GPRASP2 | c.1387C>A p.L463I | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.272); catalogued as COSV59992558; called by muse, mutect2, varscan2
- HDX | c.1544C>G p.P515R | Missense Mutation (SNP) | VAF 53/361 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs754105704; called by muse, mutect2, varscan2
- IGKV6D-21 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs777871044; called by muse, varscan2
- INTS4 | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV71087560; called by muse, mutect2, varscan2
- KCNG2 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 71/222 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs754010488; called by muse, mutect2, varscan2
- KDM2B | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV100997255, COSV65644773; called by muse, mutect2, varscan2
- KLHL34 | c.1823C>A p.A608E | Missense Mutation (SNP) | VAF 47/309 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.029); catalogued as COSV101070005; called by muse, mutect2, varscan2
- KMT2D | c.11281C>T p.P3761S | Missense Mutation (SNP) | VAF 18/628 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV56488953; called by muse, mutect2
- LILRB4 | c.1241C>G p.A414G (on ENST00000391733 / NM_001278428.3; = p.A413G on NM_001278426.3) | Missense Mutation (SNP) | VAF 83/421 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54408288; called by muse, mutect2, varscan2
- LONRF3 | c.1812G>T p.G604= (on ENST00000371628 / NM_001031855.3; = p.G563= on NM_024778.5) | Splice Region (SNP) | VAF 18/121 reads (15%) | catalogued as COSV59153938; called by muse, mutect2
- LRP1B | c.9309G>A p.W3103* | Nonsense Mutation (SNP) | VAF 47/124 reads (38%) | catalogued as COSV67238675; called by muse, mutect2, varscan2
- MALRD1 | c.2872G>A p.A958T | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs1421608506; called by muse, mutect2, varscan2
- MDN1 | c.507G>T p.W169C | Missense Mutation (SNP) | VAF 97/474 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101021935; called by muse, mutect2, varscan2
- MTCL1 | c.4150del p.V1384Cfs*12 (on ENST00000306329 / NM_001378206.1; = p.V1065Cfs*12 on NM_015210.4) | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as COSV60411496; called by mutect2, pindel, varscan2
- NEBL | c.2900C>G p.A967G | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs1387133065; called by muse, mutect2, varscan2
- NLRP13 | c.146del p.Q49Rfs*12 | Frame Shift Del (DEL) | VAF 62/366 reads (17%) | catalogued as rs768370432; called by mutect2, varscan2
- NLRP13 | c.145del p.Q49Rfs*12 | Frame Shift Del (DEL) | VAF 43/385 reads (11%) | catalogued as rs1198298310; called by mutect2*, pindel, varscan2*
- OR2A12 | c.859del p.L287Sfs*10 | Frame Shift Del (DEL) | VAF 35/173 reads (20%) | catalogued as rs1157597538; called by mutect2, pindel, varscan2
- OR2F2 | c.919A>C p.K307Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1371078282; called by muse, mutect2, varscan2
- OR4A16 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.259); catalogued as COSV59045259; called by muse, mutect2, varscan2
- OR8U1 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs766390858, COSV100163784; called by muse, mutect2, varscan2
- PRDM9 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 71/516 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV57004209; called by muse, mutect2, varscan2
- PTPRF | c.4371G>A p.R1457= | Splice Region (SNP) | VAF 21/56 reads (38%) | catalogued as rs1212688237; called by muse, mutect2, varscan2
- RBM23 | c.1168del p.A390Pfs*11 (on ENST00000359890 / NM_001077351.2; = p.A374Pfs*11 on NM_018107.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 27/116 reads (23%) | catalogued as rs869292778; called by mutect2, varscan2*
- RP1 | c.4535A>T p.K1512M | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.453); catalogued as COSV55126169; called by muse, mutect2, varscan2
- RSPO3 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100759661; called by muse, mutect2, varscan2
- RYR3 | c.1554C>A p.N518K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1431001801; called by muse, mutect2, varscan2
- SECISBP2 | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 352/782 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.182); catalogued as COSV60530554; called by muse, mutect2, varscan2
- SLC25A34 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 92/310 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as rs146057979; called by muse, mutect2, varscan2
- SLITRK2 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100157850; called by muse, varscan2
- TBC1D25 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 37/302 reads (12%) | catalogued as COSV100952085; called by muse, mutect2, varscan2
- TFEC | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV99625071; called by muse, mutect2, varscan2
- TRANK1 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 105/461 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.551); catalogued as rs757396295; called by muse, mutect2, varscan2
- TUBB8 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 140/589 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV59116909; called by muse, mutect2, varscan2
- XIAP | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100848832; called by muse, mutect2, varscan2
- ZIC4 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 185/1616 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs1252583616; called by muse, mutect2, varscan2
- ACCSL | c.66C>A p.D22E | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- ACP2 | c.239G>C p.G80A | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSL6 | c.1538C>A p.P513Q (on ENST00000379240; = p.P538Q on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ADAMTS13 | c.2726G>T p.G909V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS7 | c.3425C>A p.P1142H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRL1 | c.578G>T p.W193L (on ENST00000340736 / NM_001008701.3; = p.W188L on NM_014921.5) | Missense Mutation (SNP) | VAF 13/362 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- ADGRL4 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AKAP14 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.177); called by muse, mutect2
- ANGPTL4 | c.414G>T p.Q138H | Missense Mutation (SNP) | VAF 147/556 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ANO5 | c.2174A>G p.H725R | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- AR | c.2649C>G p.I883M | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARHGEF18 | c.2067A>C p.K689N (on ENST00000359920 / NM_001130955.2; = p.K585N on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF40 | c.1574A>T p.D525V | Missense Mutation (SNP) | VAF 125/494 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A1 | c.3177G>T p.M1059I | Missense Mutation (SNP) | VAF 51/397 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATRNL1 | c.121A>T p.S41C | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- BCAP31 | c.253A>T p.N85Y | Missense Mutation (SNP) | VAF 58/408 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- BHLHE22 | c.707A>G p.K236R | Missense Mutation (SNP) | VAF 120/493 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BMS1 | c.902-2A>G p.X301_splice | Splice Site (SNP) | VAF 14/58 reads (24%) | called by muse, varscan2
- C6 | c.588-1G>C p.X196_splice | Splice Site (SNP) | VAF 48/286 reads (17%) | called by muse, mutect2, varscan2
- CACNA1A | c.3299A>T p.K1100M | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CCDC168 | c.15080C>T p.P5027L | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CCDC50 | c.536A>C p.H179P | Missense Mutation (SNP) | VAF 178/321 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC7 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CDC14C | c.1420G>T p.V474F (on ENST00000428251; = p.V367F on NM_152627.3) | Missense Mutation (SNP) | VAF 74/385 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CDH8 | c.720C>A p.Y240* | Nonsense Mutation (SNP) | VAF 37/257 reads (14%) | called by muse, mutect2, varscan2
- CDS2 | c.1114A>G p.T372A | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CFAP46 | c.2996A>G p.N999S | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- CHST4 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.015); called by muse, mutect2
- CHSY3 | c.234del p.A79Rfs*99 | Frame Shift Del (DEL) | VAF 62/346 reads (18%) | called by mutect2, pindel, varscan2
- CLCN5 | c.1981T>A p.Y661N | Missense Mutation (SNP) | VAF 42/334 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPAMD8 | c.2357C>G p.T786R (on ENST00000651564; = p.T739R on NM_015692.5) | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPSF1 | c.2744G>T p.G915V | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, varscan2
- CRACR2A | c.1820A>G p.Y607C | Missense Mutation (SNP) | VAF 74/348 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTDSP2 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CTNNA3 | c.1847C>A p.T616K | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- DMGDH | c.1837A>T p.K613* | Nonsense Mutation (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- DNAH8 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- DRP2 | c.2106C>G p.Y702* | Nonsense Mutation (SNP) | VAF 19/175 reads (11%) | called by muse, mutect2, varscan2
- DYRK2 | c.1779G>T p.R593S (on ENST00000344096 / NM_006482.3; = p.R520S on NM_003583.4) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- EGFL6 | c.1373C>A p.P458H | Missense Mutation (SNP) | VAF 74/540 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- EHD4 | c.1536G>T p.K512N | Missense Mutation (SNP) | VAF 53/435 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- EMSY | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F2 | c.1196G>T p.R399L | Missense Mutation (SNP) | VAF 101/568 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- FAM122B | c.331T>A p.F111I | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- FAM47A | c.127A>T p.M43L | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FAM71E2 | c.2138_2144del p.K713Ifs*20 | Frame Shift Del (DEL) | VAF 15/117 reads (13%) | called by mutect2, pindel, varscan2
- FLG | c.712A>T p.T238S | Missense Mutation (SNP) | VAF 124/590 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GLUD2 | c.547A>T p.K183* | Nonsense Mutation (SNP) | VAF 57/444 reads (13%) | called by muse, mutect2, varscan2
- GMPS | c.1907T>C p.V636A | Missense Mutation (SNP) | VAF 59/479 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- GOLGA8K | c.1783A>T p.K595* | Nonsense Mutation (SNP) | VAF 192/571 reads (34%) | called by muse, mutect2, varscan2
- GPRIN1 | c.2579A>T p.Q860L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- H2BW2 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 83/373 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HGF | c.953A>T p.N318I | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- HRNR | c.7013C>A p.S2338Y | Missense Mutation (SNP) | VAF 360/1069 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HUWE1 | c.10761G>T p.V3587= | Splice Region (SNP) | VAF 48/460 reads (10%) | called by muse, mutect2
- IRS4 | c.2357C>A p.A786D | Missense Mutation (SNP) | VAF 65/417 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- KCNC2 | c.372C>G p.H124Q | Missense Mutation (SNP) | VAF 130/752 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- KDM4B | c.1222G>T p.V408L | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, varscan2
- KIAA1210 | c.1465C>A p.L489M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- KRTAP24-1 | c.152A>C p.Y51S | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MS4A14 | c.1102C>G p.Q368E | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MUC12 | c.10115C>A p.T3372K (on ENST00000379442; = p.T3229K on NM_001164462.1) | Missense Mutation (SNP) | VAF 76/2828 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2
- NEK11 | c.386T>C p.I129T | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- NOS1 | c.3925del p.V1309Sfs*36 | Frame Shift Del (DEL) | VAF 48/353 reads (14%) | called by mutect2, pindel, varscan2
- NR1D2 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NR5A2 | c.937C>A p.P313T (on ENST00000367362 / NM_205860.3; = p.P267T on NM_003822.5) | Missense Mutation (SNP) | VAF 196/600 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ODAPH | c.44G>A p.W15* | Nonsense Mutation (SNP) | VAF 39/154 reads (25%) | called by muse, mutect2, varscan2
- OR2J3 | c.45T>A p.F15L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- OR2T6 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR5D16 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- PCDH11X | c.2951G>C p.S984T | Missense Mutation (SNP) | VAF 121/607 reads (20%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- PCDHB10 | c.348T>G p.I116M | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2
- PCDHGB3 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 89/475 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- PCDHGC4 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- PCSK2 | c.561C>A p.Y187* | Nonsense Mutation (SNP) | VAF 66/311 reads (21%) | called by muse, mutect2, varscan2
- PDHA2 | c.353C>A p.A118D | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNA3 | c.5128G>T p.D1710Y | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAME | c.1386_1403del p.Y462_R468delins* | Nonsense Mutation (DEL) | VAF 117/442 reads (26%) | called by mutect2, pindel, varscan2
- RAD51 | c.474G>C p.M158I | Missense Mutation (SNP) | VAF 36/538 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2
- RAMP3 | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- RBBP4 | c.281A>T p.D94V | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SEZ6L | c.1481A>C p.H494P | Missense Mutation (SNP) | VAF 137/272 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIGLEC11 | c.1311C>A p.H437Q | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC12A5 | c.193G>A p.G65S (on ENST00000454036 / NM_001134771.2; = p.G42S on NM_020708.5) | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- SLC35A2 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 92/619 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC6A5 | c.1407T>A p.D469E | Missense Mutation (SNP) | VAF 81/443 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC9A3R1 | c.903C>A p.D301E | Missense Mutation (SNP) | VAF 52/367 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLITRK4 | c.1456A>G p.K486E | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SOX3 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- SPDEF | c.26G>T p.S9I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2
- SPEG | c.1354G>T p.A452S | Missense Mutation (SNP) | VAF 137/333 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPTBN1 | c.3581A>T p.H1194L | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SRGAP3 | c.2274del p.S759Pfs*40 | Frame Shift Del (DEL) | VAF 103/446 reads (23%) | called by mutect2, pindel, varscan2
- ST3GAL5 | c.1106A>G p.D369G (on ENST00000377332; = p.D409G on NM_003896.4) | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D1 | c.1653G>T p.E551D | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, varscan2
- TCP10L2 | c.499-1G>T p.X167_splice | Splice Site (SNP) | VAF 30/288 reads (10%) | called by mutect2, varscan2
- TEX13C | c.1589C>A p.P530Q | Missense Mutation (SNP) | VAF 117/541 reads (22%) | SIFT tolerated (0.11); called by muse, mutect2, varscan2
- TFCP2L1 | c.768+1G>T p.X256_splice | Splice Site (SNP) | VAF 95/221 reads (43%) | called by muse, mutect2, varscan2
- TKTL1 | c.688A>T p.S230C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- TM9SF4 | c.447C>G p.N149K | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TPTE | c.1302A>T p.Q434H (on ENST00000618007 / NM_199261.4; = p.Q416H on NM_199259.4) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.216); called by muse, mutect2
- TRHDE | c.2544A>G p.I848M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE2W | c.76A>T p.N26Y | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- UBTFL1 | c.51G>T p.R17S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2
- UTP14A | c.266A>T p.D89V | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- VWA5A | c.1889A>T p.K630M | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XRN1 | c.816A>T p.K272N | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2
- ZNF208 | c.1703T>C p.L568P | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF365 | c.959G>A p.C320Y | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ARHGEF12 | c.3591G>T p.L1197= | Silent (SNP) | VAF 41/196 reads (21%) | called by muse, mutect2, varscan2
- CENPO | c.69G>A p.R23= | Silent (SNP) | VAF 37/165 reads (22%) | catalogued as rs772776255; called by muse, mutect2, varscan2
- COL2A1 | c.4146C>A p.S1382= | Silent (SNP) | VAF 65/306 reads (21%) | called by muse, mutect2, varscan2
- COL6A1 | c.2121G>T p.L707= | Silent (SNP) | VAF 63/333 reads (19%) | called by muse, mutect2, varscan2
- COL6A2 | c.273G>T p.A91= | Silent (SNP) | VAF 129/689 reads (19%) | catalogued as rs753168760; called by muse, mutect2, varscan2
- CYP7A1 | c.1284C>A p.L428= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV56962245; called by muse, mutect2, varscan2
- DISC1 | c.2097A>C p.R699= | Silent (SNP) | VAF 28/69 reads (41%) | called by muse, varscan2
- DNAH8 | c.8604T>C p.A2868= | Silent (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- DOCK2 | c.93C>A p.I31= | Silent (SNP) | VAF 58/380 reads (15%) | called by muse, mutect2, varscan2
- DOCK4 | c.4320A>G p.R1440= | Silent (SNP) | VAF 26/242 reads (11%) | called by muse, mutect2, varscan2
- ERLIN1 | c.1023C>A p.I341= | Silent (SNP) | VAF 51/237 reads (22%) | called by muse, mutect2, varscan2
- FGFBP3 | c.609G>A p.K203= | Silent (SNP) | VAF 41/197 reads (21%) | called by muse, mutect2, varscan2
- FKBP6 | c.504G>C p.L168= | Silent (SNP) | VAF 127/502 reads (25%) | catalogued as COSV52723839; called by muse, mutect2, varscan2
- HTR3A | c.1422C>A p.I474= | Silent (SNP) | VAF 102/567 reads (18%) | called by muse, mutect2, varscan2
- IDH3G | c.690G>T p.G230= | Silent (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- JSRP1 | c.753G>A p.R251= | Silent (SNP) | VAF 155/748 reads (21%) | called by muse, mutect2, varscan2
- KLC4 | c.369G>T p.L123= | Silent (SNP) | VAF 172/679 reads (25%) | catalogued as COSV52437579; called by muse, mutect2, varscan2
- LPCAT4 | c.663C>T p.I221= | Silent (SNP) | VAF 75/328 reads (23%) | catalogued as rs757684300; called by muse, mutect2, varscan2
- LRFN5 | c.24G>T p.L8= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV53247418; called by muse, varscan2
- MROH7 | c.2989C>A p.R997= | Silent (SNP) | VAF 22/324 reads (7%) | catalogued as COSV100273822; called by muse, mutect2
- ORC3 | c.1617A>G p.L539= | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2
- PCDHB11 | c.471G>A p.A157= | Silent (SNP) | VAF 43/212 reads (20%) | catalogued as rs781852727; called by muse, mutect2, varscan2
- PHRF1 | c.2925C>T p.D975= (on ENST00000264555 / NM_001286581.2; = p.D974= on NM_020901.4) | Silent (SNP) | VAF 34/231 reads (15%) | catalogued as rs372886688; called by muse, mutect2, varscan2
- PKD1 | c.10935C>T p.R3645= (on ENST00000262304 / NM_001009944.3; = p.R3644= on NM_000296.4) | Silent (SNP) | VAF 93/322 reads (29%) | catalogued as rs766568353, CD119088; called by muse, mutect2, varscan2
- PKD1 | c.1212G>T p.P404= | Silent (SNP) | VAF 125/567 reads (22%) | called by muse, mutect2, varscan2
- POLR2A | c.3081C>T p.D1027= | Silent (SNP) | VAF 113/395 reads (29%) | catalogued as rs748992041; called by muse, mutect2, varscan2
- PRODH2 | c.711G>T p.V237= (on ENST00000301175; = p.V161= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 45/361 reads (12%) | called by muse, mutect2, varscan2
- RIMS1 | c.4806T>C p.P1602= | Silent (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- SIPA1 | c.435C>A p.T145= | Silent (SNP) | VAF 105/509 reads (21%) | called by muse, mutect2, varscan2
- SIRPB2 | c.42G>A p.L14= | Silent (SNP) | VAF 36/175 reads (21%) | called by muse, mutect2, varscan2
- SLC35E3 | c.715T>C p.L239= | Silent (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- TCEAL7 | c.165G>A p.R55= | Silent (SNP) | VAF 31/220 reads (14%) | called by muse, mutect2, varscan2
- TNR | c.744G>C p.G248= | Silent (SNP) | VAF 193/513 reads (38%) | catalogued as COSV99691347; called by muse, mutect2, varscan2
- TRIM64B | c.801A>G p.P267= | Silent (SNP) | VAF 44/516 reads (9%) | called by muse, mutect2
- VWA5B1 | c.1059G>A p.P353= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as rs369881324; called by muse, mutect2, varscan2
- ABI3BP | c.1786+594A>G | Intron (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2, varscan2
- AC079154.1 | n.905G>T | RNA (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826219 A>T | 3'Flank (SNP) | VAF 104/363 reads (29%) | called by muse, mutect2, varscan2
- AMPH | c.1182+1366C>A | Intron (SNP) | VAF 17/93 reads (18%) | catalogued as COSV57731982; called by muse, mutect2, varscan2
- C1S | c.5+14G>A | Intron (SNP) | VAF 125/625 reads (20%) | called by muse, mutect2, varscan2
- CDH9 | c.999+49G>T | Intron (SNP) | VAF 42/165 reads (25%) | called by muse, mutect2, varscan2
- CES5A | c.-12G>T | 5'UTR (SNP) | VAF 40/189 reads (21%) | catalogued as rs763597097; called by muse, mutect2, varscan2
- DUOX2 | c.716-43G>T | Intron (SNP) | VAF 13/106 reads (12%) | called by muse, mutect2, varscan2
- ENDOV | chr17:80415095 C>T | 5'Flank (SNP) | VAF 141/937 reads (15%) | called by muse, mutect2, varscan2
- FAM161A | c.*659G>T | 3'UTR (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- IRAK3 | c.134-6826A>G | Intron (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2
- KITLG | c.-21A>G | 5'UTR (SNP) | VAF 95/526 reads (18%) | called by muse, mutect2, varscan2
- LIG1 | c.-83G>C | 5'UTR (SNP) | VAF 79/379 reads (21%) | called by muse, mutect2, varscan2
- LINC02206 | n.375G>C | RNA (SNP) | VAF 46/235 reads (20%) | called by muse, mutect2, varscan2
- LRCOL1 | c.*31G>T | 3'UTR (SNP) | VAF 81/372 reads (22%) | called by muse, mutect2, varscan2
- PDE3A | c.1011+56G>T | Intron (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- PDE3A | c.1011+57G>T | Intron (SNP) | VAF 22/175 reads (13%) | called by muse, mutect2, varscan2
- PORCN | c.374-24C>G | Intron (SNP) | VAF 85/364 reads (23%) | called by muse, mutect2, varscan2
- RCC1 | chr1:28505967 G>A | 5'Flank (SNP) | VAF 49/191 reads (26%) | catalogued as COSV63120776; called by muse, mutect2, varscan2
- RUNX1T1 | c.1280-3846del | Intron (DEL) | VAF 22/142 reads (15%) | catalogued as COSV56142423; called by mutect2, pindel, varscan2
- SCAMP4 | c.-33A>C | 5'UTR (SNP) | VAF 16/384 reads (4%) | called by muse, mutect2
- SNORD52 | chr6:31837152 A>G | 3'Flank (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- STMN2 | c.-17G>A | 5'UTR (SNP) | VAF 81/339 reads (24%) | catalogued as rs1170390148, COSV55222330; called by muse, mutect2, varscan2
- SYT8 | c.-9G>A | 5'UTR (SNP) | VAF 98/438 reads (22%) | catalogued as rs1018705753; called by muse, mutect2, varscan2
